Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A7BW, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A7BW-01A (Primary Tumor).

[page 1 of 2]
CLINICAL NOTES

1. Gastrectomy total.
2. Donuts.
3. R gastroepiploic.

MACROSCOPY

- a. Specimen is labelled stomach. Total gastrectomy specimen, 120mm along the lesser curve, approximately 195mm along the greater curve. The large portion of the body of the stomach, the wall is thickened and indurated, and the mucosa granular and congested with loss of the normal rugal folds. No proliferative mucosal lesion is seen. There is a relatively sharp contrast with normal antral mucosa. The fat around both lesser and greater curves, is indurated. Omentum is included showing obvious abnormality. On slicing the thickened wall shows some pallor. Composite longitudinal section taken from mid portion of stomach to distal margin in blocks A1-A4. A5 & A6 also composite blocks also representing sections to proximal margin along lesser curve. Random section of omentum block A7. Blocks A8&A9 greater curve lymph nodes A10 lesser curve lymph nodes. X in 10 TP.
- b. Specimen is labelled donuts proximal oesophageal and distal small bowel. 2 pieces of ragged tissue received in the same container, the largest with an external diameter of approximately 17mm. Most NX in 1P.
- c. Specimen is labelled right gastroepiploic nodes. Ragged piece of fatty tissue, up to 23mm. No definite node identified. AX in 1.

MICROSCOPY

- a. Sections taken from the abnormal thickened area described macroscopically showed diffuse pattern poorly differentiated adenocarcinoma, which infiltrates through the full thickness of the gastric wall, into perigastric fat. The cells are poorly cohesive. The minor component have a signet-ring pattern, but generally the cells are pleomorphic, with variable quantitative cytoplasm. Tumour extends to the gastro-oesophageal junction, where there is a small nodule of gland forming tumour, beneath squamous epithelium. Intramucosal tumour is identified in this region, unlikely the remainder of the stomach, where the tumour is predominantly submucosal and intramural. Tumour extends close to the proximal margin but does not involve it. Two (2) greater curve lymph nodes were identified, both showing metastatic carcinoma. There is extensive infiltration of surrounding fat by tumour. Five lesser curve nodes were retrieved, all showing metastatic adenocarcinoma. Again there is extensive infiltration of the surrounding fat. Sections of omentum show no significant abnormality.
- b. Sections of proximal and distal resection rings representing portions of oesophagus and duodenum, show no evidence of involvement by tumour.
- c. Sections show fat with a single lymph node. The latter shows extensive sinusoidal infiltration by metastatic adenocarcinoma.

DIAGNOSIS

1 & 2. Total gastrectomy specimen extensively infiltrated by diffuse type poorly differentiated adenocarcinoma (linitis plastica pattern), with full thickness wall infiltration and metastases in 7

ICD C-3

Adenocarcinoma, diffuse
Type 8145/3
Site ^{CLF} Fundus of stomach
^{path} C16.1
Stomach NOS C16.9
JW 9/25/13

[page 2 of 2]
of 7 lesser and greater curve lymph nodes. Surgical margins are clear. pT3N2Mx

3. Right gastroepiploic lymph node showing metastatic adenocarcinoma.

Source: NCI Genomic Data Commons file 3eb06a63-cd66-4907-8594-98f8f75a3501 (TCGA-RD-A7BW.A666F7AA-8844-4334-BCBE-ABEC62792C3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).